Gene-level copy-number profile of tumor specimen TCGA-AO-A03O-01A from TCGA case TCGA-AO-A03O, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 69.4 years (25,362 days).
Specimen TCGA-AO-A03O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.e866c189-b2f5-4948-afcf-adfc6ff323eb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AO-A03O-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b6c2a91a-6366-44d5-82b8-60438c462d61

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,693; copy number 2: 6,715; copy number 3: 26,658; copy number 4: 14,145; copy number 5: 6,427; copy number 6: 1,351; copy number 7: 467; copy number 8: 566; copy number 9: 220; copy number 10: 308; copy number 11: 316; copy number 12: 424; copy number 13: 124; copy number 14: 140; copy number 15: 5; copy number 16: 90; copy number 17: 4; copy number 18: 5; copy number 19: 15; copy number 21: 25; copy number 22: 2; copy number 31: 20; copy number 32: 90.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AO-A03O-01A-11D-A011-01): tumor purity 0.65, ploidy 3.61, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,821 genes in 51 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:231,925,834–236,286,960, 102 genes, copy number 8 (broad region; genes not listed).
- chr1:240,014,348–241,357,230, 23 genes, copy number 8 (within-gene range 5–8): FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8, RGS7, RFKP1, HNRNPA1P42, AL590682.1, MIR3123.
- chr2:97,713,576–98,936,259, 18 genes, copy number 7: ZAP70, TMEM131, HMGN1P36, RNU7-96P, VWA3B, ATP5F1BP1, AC092675.1, CNGA3, AC092675.2, INPP4A, COA5, UNC50, MGAT4A, YWHAQP5, LINC02611, RNU4-84P, CRACDL, RNU7-46P.
- chr3:4,269,153–7,741,533, 31 genes, copy number 8–14 (within-gene range 3–14): AC023483.1, SETMAR, MRPS10P2, ITPR1-DT, ITPR1, EGOT, AC018816.2, AC018816.1, BHLHE40-AS1, BHLHE40, RNF10P1, UBTFL8, Y_RNA, AC090955.1, ARL8B, AC026202.2, AC026202.3, EDEM1, MIR4790, RN7SL553P, AC026202.1, AC087857.1, AC026167.1, AC027119.1, AC069277.1, GRM7-AS3, AC069277.2, GRM7, MRPS36P1, GRM7-AS2, AC066585.1.
- chr3:12,733,528–14,556,075, 34 genes, copy number 7–14 (within-gene range 6–14): TMEM40, KRT18P17, CAND2, AC034198.2, RPL32, SNORA7A, AC034198.1, LINC02022, IQSEC1, AC069271.1, NUP210, AC027124.2, AC027124.1, HDAC11-AS1, HDAC11, FBLN2, LINC00620, WNT7A, VN1R20P, FGD5P1, TPRXL, AC090004.2, VN1R21P, CHCHD4, TMEM43, AC090004.1, XPC-AS1, XPC, LSM3, AC093496.1, LINC01267, RNA5SP124, SLC6A6, GRIP2.
- chr3:83,384,445–86,074,429, 10 genes, copy number 7–11 (within-gene range 3–11): AC023503.1, AC092825.1, SRRM1P2, AC117464.1, LINC00971, AC117482.1, LINC02025, AC132660.2, CADM2, MIR5688.
- chr4:33,238,239–36,641,939, 22 genes, copy number 7–14: AC093878.1, AC097535.2, AC097535.1, AC079772.1, AC016687.3, AC016687.2, AC016687.1, LINC02484, AC110790.1, AC093689.1, AC093913.1, AC020589.1, SEC63P2, RNU6-573P, ARAP2, AC098827.1, AC104078.1, DTHD1, AC104078.2, MIR1255B1, LINC02505, AC125336.1.
- chr4:58,524,515–58,988,182, 4 genes, copy number 11 (within-gene range 4–11): LINC02494, AC019133.1, AC017091.1, LINC02619.
- chr4:61,775,449–62,510,771, 10 genes, copy number 7: AC108161.1, Y_RNA, ADGRL3-AS1, RPS15AP17, AC007511.1, RPL21P47, AC105313.1, AC074087.2, AC074087.1, HMGN1P11.
- chr4:72,807,267–76,783,253, 90 genes, copy number 9–11 (within-gene range 6–11) (broad region; genes not listed).
- chr4:79,225,694–82,044,244, 25 genes, copy number 7: NAA11, GK2, LINC00989, OR7E94P, AC092542.1, LINC02469, PCAT4, SNORA75, ANTXR2, KPNA2P1, RPSAP39, AC021127.1, PRDM8, FGF5, CFAP299, AC105917.1, BMP3, PRKG2, PRKG2-AS1, RNU5A-2P, RASGEF1B, MTCYBP44, COX5BP1, AC021863.1, NPM1P41.
- chr5:12,553,890–14,532,128, 13 genes, copy number 7 (within-gene range 5–7): AC106771.1, LINC01194, AC106794.2, AC106794.1, LINC02220, AC016553.1, RPS23P5, NENFP3, AC016546.1, DNAH5, AC016576.1, TRIO, AC016549.1.
- chr5:16,451,519–19,234,487, 67 genes, copy number 8–13 (broad region; genes not listed).
- chr5:28,213,359–29,600,868, 19 genes, copy number 7: AC093300.1, LINC02103, AC008825.1, AC109472.1, RNU6-909P, AC008825.2, LINC02109, AC010385.2, LSP1P3, AC010385.1, AC010385.3, SUCLG2P4, AC024589.2, AC024589.1, AC024589.3, AC112172.2, LINC02064, AC027345.1, UBL5P1.
- chr6:91,390,313–91,816,428, 8 genes, copy number 7: AL080284.1, MIR4643, CASC6, MTATP6P25, MTND4LP19, MTCO1P56, RN7SL415P, AL590635.1.
- chr6:100,881,471–102,453,792, 8 genes, copy number 7–10: AL133338.1, AL133338.2, GRIK2, ACTG1P18, AP002528.1, AP002530.1, AL357139.2, AL357139.1.
- chr6:104,936,616–107,459,564, 41 genes, copy number 14–21 (within-gene range 6–21): LIN28B, RNU6-1106P, BVES, BVES-AS1, POPDC3, PREP, AL133406.2, AL133406.1, RPL35P3, AL096794.1, LINC02836, Z97206.1, AL591518.1, RN7SKP211, PRDM1, ATG5, AL022067.1, U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12.
- chr6:117,907,264–119,391,829, 20 genes, copy number 9–18 (within-gene range 6–18): SLC35F1, AL450405.1, AL589993.1, CEP85L, BRD7P3, PLN, Z99496.1, SSXP10, SELENOKP3, MCM9, ASF1A, AL137009.1, FAM184A, Y_RNA, MIR548B, AL022722.2, MAN1A1, AL022722.1, RNU6-194P, AL078600.1.
- chr7:62,275,361–66,493,566, 162 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr8:58,227,578–145,066,685, 1,343 genes, copy number 7–22 (broad region; genes not listed).
- chr10:90,871,952–91,284,337, 11 genes, copy number 8–12: RPP30, Y_RNA, ANKRD1, RNU6-740P, AL365434.1, AL365434.2, LINC00502, DDX18P6, NUDT9P1, AL731553.1, PCGF5.
- chr10:105,534,659–105,904,771, 5 genes, copy number 7 (within-gene range 5–7): RNU6-463P, PPIAP38, YWHAZP5, LINC02627, AL731574.1.
- chr10:120,608,580–121,185,966, 9 genes, copy number 12 (within-gene range 4–12): AC023282.1, WDR11-AS1, AL391425.1, WDR11, AC010998.2, AC010998.1, AC010998.3, RPL19P16, LINC01153.
- chr10:122,374,696–122,826,868, 10 genes, copy number 9 (within-gene range 4–9): PLEKHA1, MIR3941, BX842242.1, ARMS2, HTRA1, DMBT1, AL603764.1, AL603764.2, C10orf120, DMBT1L1.
- chr11:68,612,899–71,639,769, 84 genes, copy number 9–16 (broad region; genes not listed).
- chr12:45,164,186–46,876,784, 27 genes, copy number 8: AC009248.3, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4.
- chr12:56,923,133–61,232,937, 100 genes, copy number 7–12 (broad region; genes not listed).
- chr12:62,545,582–64,222,296, 38 genes, copy number 7–11: RNU6-399P, LINC01465, AC048341.1, MIRLET7I, AC048341.2, PPM1H, RPL32P26, GAPDHP44, RNU1-83P, Y_RNA, RPL14P1, AC078814.2, LDHAL6CP, AC078814.1, RSL24D1P5, AVPR1A, AC135584.1, HNRNPA1P69, AC026116.1, DPY19L2, AC084357.2, AC027667.1, AC084357.3, AC084357.1, RXYLT1, RXYLT1-AS1, PABPC1P4, SRGAP1, RPL36AP41, AC079866.2, AC079866.1, AC020611.1, AC020611.2, AC025576.3, AC025576.2, AC025576.1, C12orf66, RNU6-1009P.
- chr12:66,950,754–67,753,817, 15 genes, copy number 7–9: AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, AC078983.1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1.
- chr12:68,842,197–70,443,923, 34 genes, copy number 7–31 (within-gene range 3–31): CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P.
- chr12:71,664,301–72,186,618, 11 genes, copy number 7 (within-gene range 5–7): THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1.
- chr12:73,115,957–74,402,600, 11 genes, copy number 9 (within-gene range 3–9): AC090503.2, LINC02444, AC090503.1, AC087879.1, RNU6-1012P, LINC02445, U8, LINC02882, AC136188.1, LINC02394, AC090502.3.
- chr12:76,763,588–77,317,234, 7 genes, copy number 9 (within-gene range 3–9): ZDHHC17, CSRP2, AC124784.1, AC025161.1, E2F7, AC079030.1, LINC02464.
- chr14:25,124,467–32,272,301, 98 genes, copy number 14–32 (broad region; genes not listed).
- chr16:47,218,026–48,363,122, 23 genes, copy number 8: AC007494.3, AC007494.1, AC007533.1, Y_RNA, 5S_rRNA, PHKB, RNA5SP425, AC007599.2, AC007599.1, EIF4BP5, NDUFA5P11, LINC02133, AC141846.1, LINC02192, LINC02134, AC096996.3, AC096996.1, ABCC12, AC096996.2, ABCC11, LONP2, UBA52P8, AC023818.1.
- chr18:30,713,275–32,938,316, 57 genes, copy number 12–16: AC090506.1, AC090506.2, AC016382.1, RNU6-857P, DSC3, DSC2, DSCAS, DSC1, AC012417.1, DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA, DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52, TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2, GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2, HNRNPA1P7, AC025887.2, WBP11P1, AC009835.1, AC025887.1, KLHL14, AC012123.1, AC012123.2, AC090371.2.
- chr20:38,033,725–43,189,970, 84 genes, copy number 7–15 (within-gene range 4–15) (broad region; genes not listed).
- chr20:49,503,874–50,321,342, 26 genes, copy number 7–9: PTGIS, B4GALT5, RN7SL197P, SNRPFP1, RNU6-919P, SLC9A8, AL162615.1, SPATA2, Y_RNA, Metazoa_SRP, RNF114, KRT18P4, RNU6-147P, SNAI1, TRERNA1, UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271.
- chr20:52,192,159–54,859,812, 35 genes, copy number 8 (within-gene range 4–8): LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL161945.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5, RNU4ATAC7P.
- chr20:55,408,898–58,783,821, 73 genes, copy number 7–17 (within-gene range 6–17) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,693. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
